Somatic mutation profile of tumor specimen 0DVR7X from CCDI case PBCNFI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Epithelial tumor, benign; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 14.8 years (5,394 days).
Specimen 0DVR7X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faa01e5f-f134-4bed-a9a3-c49403c4589f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVR5Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a03ee96-aa74-4a1b-825e-653704a401f5

The open-access MAF lists 55 somatic variants for this specimen: 30 protein-altering or splice-affecting, 15 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 15, Intron 4, Nonsense Mutation 3, 5'UTR 3, Frame Shift Del 2, 3'UTR 1, RNA 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 136/314 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 194/456 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 147/338 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD27 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 103/253 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768883640; called by muse, mutect2, varscan2
- AQP1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 118/320 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs183830991; called by muse, mutect2, varscan2
- ATRX | c.5807del p.K1936Rfs*19 | Frame Shift Del (DEL) | VAF 160/178 reads (90%) | catalogued as COSV64873056, COSV64882465; called by mutect2, varscan2
- FOXO4 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs374390953; called by muse, mutect2, varscan2
- LY75 | c.3221C>T p.T1074M | Missense Mutation (SNP) | VAF 267/620 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as rs372948084; called by muse, mutect2, varscan2
- MTUS2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 175/260 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs753146187, COSV70922099; called by muse, mutect2, varscan2
- OR2A12 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 35/631 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV68822086; called by muse, mutect2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 324/610 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, mutect2, varscan2
- USP39 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 145/348 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs760611682; called by muse, mutect2, varscan2
- ARFGEF3 | c.6184C>A p.P2062T | Missense Mutation (SNP) | VAF 101/178 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ARHGAP20 | c.2272A>T p.K758* | Nonsense Mutation (SNP) | VAF 241/547 reads (44%) | called by muse, mutect2, varscan2
- BAIAP3 | c.235T>G p.W79G | Missense Mutation (SNP) | VAF 86/180 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- BCOR | c.1807del p.A603Pfs*66 | Frame Shift Del (DEL) | VAF 88/98 reads (90%) | called by mutect2, varscan2
- C1QB | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, varscan2
- CDH12 | c.110A>T p.E37V | Missense Mutation (SNP) | VAF 34/622 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.383); called by muse, mutect2
- CEP120 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 30/947 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.072); called by muse, mutect2
- DCAF1 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 33/651 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- DENND1C | c.1687A>G p.I563V | Missense Mutation (SNP) | VAF 144/232 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ETAA1 | c.2293A>C p.S765R | Missense Mutation (SNP) | VAF 209/480 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRN3 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 172/416 reads (41%) | called by muse, mutect2, varscan2
- SCN11A | c.2515T>A p.F839I | Missense Mutation (SNP) | VAF 237/272 reads (87%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SGO2 | c.3755T>C p.F1252S | Missense Mutation (SNP) | VAF 67/481 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLCO3A1 | c.1373+1G>A p.X458_splice | Splice Site (SNP) | VAF 161/179 reads (90%) | called by muse, mutect2, varscan2
- SPDL1 | c.1740A>C p.K580N | Missense Mutation (SNP) | VAF 197/404 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- THSD7A | c.400C>G p.P134A | Missense Mutation (SNP) | VAF 295/546 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- TMEM232 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 17/594 reads (3%) | called by muse, mutect2
- TRIML1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 173/611 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ARMH4 | c.1083G>A p.E361= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV50763095; called by muse, mutect2, varscan2
- ARRB1 | c.327C>T p.G109= | Silent (SNP) | VAF 141/333 reads (42%) | catalogued as rs1415966688; called by muse, mutect2, varscan2
- ASTL | c.585G>A p.T195= | Silent (SNP) | VAF 125/300 reads (42%) | catalogued as rs747604715; called by muse, mutect2, varscan2
- CD53 | c.402G>A p.A134= | Silent (SNP) | VAF 154/405 reads (38%) | catalogued as rs752405238, COSV54761506; called by muse, mutect2, varscan2
- COL5A3 | c.4740G>A p.A1580= | Silent (SNP) | VAF 194/451 reads (43%) | catalogued as rs781254667, COSV99319003; called by muse, mutect2, varscan2
- DCAF5 | c.1624C>T p.L542= | Silent (SNP) | VAF 29/185 reads (16%) | called by muse, mutect2, varscan2
- DHRS7C | c.855C>T p.Y285= (on ENST00000330255 / NM_001220493.2; = p.Y284= on NM_001105571.3) | Silent (SNP) | VAF 140/323 reads (43%) | catalogued as rs1296866792, COSV57653345; called by muse, mutect2, varscan2
- HIPK3 | c.2934A>G p.E978= | Silent (SNP) | VAF 217/461 reads (47%) | called by muse, mutect2, varscan2
- KCNQ2 | c.2547C>T p.C849= (on ENST00000359125 / NM_172107.4; = p.C821= on NM_004518.6) | Silent (SNP) | VAF 88/248 reads (35%) | catalogued as rs746730588; called by muse, mutect2, varscan2
- MBD3L1 | c.384G>A p.A128= | Silent (SNP) | VAF 155/346 reads (45%) | catalogued as rs765959320, COSV99977993; called by muse, mutect2, varscan2
- MRPL53 | c.135T>C p.T45= | Silent (SNP) | VAF 197/430 reads (46%) | called by muse, mutect2, varscan2
- NALCN | c.1245C>T p.Y415= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as rs1426944195, COSV51968781; called by muse, varscan2
- NRG2 | c.1884C>T p.A628= | Silent (SNP) | VAF 85/281 reads (30%) | catalogued as rs1277534449, COSV51204665; called by muse, mutect2, varscan2
- PIP5K1B | c.1455C>T p.Y485= | Silent (SNP) | VAF 218/519 reads (42%) | catalogued as rs1314804518, COSV55251660; called by muse, mutect2, varscan2
- TNRC18 | c.3240C>T p.P1080= | Silent (SNP) | VAF 33/177 reads (19%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- CCDC158 | c.2445+83G>T | Intron (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- CDCP2 | c.764-48T>C | Intron (SNP) | VAF 35/58 reads (60%) | called by muse, mutect2, varscan2
- FBRS | chr16:30662538 G>T | 5'Flank (SNP) | VAF 102/199 reads (51%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 10/302 reads (3%) | called by muse, mutect2
- LPCAT1 | c.816+82C>T | Intron (SNP) | VAF 12/190 reads (6%) | catalogued as rs1490556771; called by muse, mutect2
- OR2A25 | c.*29C>T | 3'UTR (SNP) | VAF 204/413 reads (49%) | catalogued as rs376884045; called by muse, mutect2, varscan2
- SCARF2 | c.-29G>A | 5'UTR (SNP) | VAF 44/117 reads (38%) | called by muse, mutect2, varscan2
- SUN3 | c.-58G>A | 5'UTR (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2, varscan2
- ZNF383 | c.-30G>A | 5'UTR (SNP) | VAF 193/466 reads (41%) | called by muse, mutect2, varscan2
